Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7J2, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7J2-01A (Primary Tumor).

ICD-O-3
Oligodendroglioma, grade III
Site Brain, supratentorial No
9451/3
C71.0
JW 9/30/13

glioma with focal evidence for malignancy.
IDH1 R132H mutation present
1p/19q loss present

Although well differentiated in most tumor
portions graded as anaplastic for focal
vascular proliferation and focally increased
proliferation

Diagnosis: anaplastic oligodendroglioma WHO grade III

untranslated original report
is housed at the BCR.

Criteria	JW 8/30/13	Yes	No

Source: NCI Genomic Data Commons file 05681616-29f3-44d0-9044-c5af7bec061b (TCGA-S9-A7J2.F7F8D6E7-0C27-4FAC-96E0-66EED6274122.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).